Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A39M, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A39M-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----
THYROID (THYROIDECTOMY):

SPECIMEN TYPE:
Total thyroidectomy

ICD-O-3

TUMOR SITE:
Left lobe

carcinoma papillary, thyroid, 8260/3
Site: thyroid, NOS C73.9
hw
9/14/11

HISTOLOGIC TYPE:
Papillary carcinoma

TUMOR SIZE:
Greatest dimension: 4 cm

FOCALITY:
Unifocal

LYMPH NODES:
None submitted

EXTENT OF INVASION
PRIMARY TUMOR:
pT2: limited to the thyroid

REGIONAL LYMPH NODES:
pNX: Cannot be assessed

DISTANT METASTASIS:
pMX: Cannot be assessed

MARGINS:
Margins are uninvolved
(distance of invasive carcinoma of nearest
margin is <1 mm.)

VENOUS/LYMPHATIC INVASION:
Absent

ADDITIONAL PATHOLOGIC FINDINGS:
Thyroiditis (lymphocytic)

Source: NCI Genomic Data Commons file 2a152299-89df-408d-b65d-04a56a745f19 (TCGA-ET-A39M.978AE60E-CA27-49D9-A338-1338005A672A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).